Somatic mutation profile of tumor specimen TCGA-B3-4104-01A (aliquot TCGA-B3-4104-01A-01D-1252-08) from TCGA case TCGA-B3-4104, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage II; Age at diagnosis: 75.9 years (27,709 days).
Specimen TCGA-B3-4104-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ccb51e1c-aecc-4446-b3aa-097447c881a6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B3-4104-10A (Blood Derived Normal), aliquot TCGA-B3-4104-10A-01D-1458-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e0134e4f-7176-447c-9198-f2b27124f952

The open-access MAF lists 79 somatic variants for this specimen: 56 protein-altering or splice-affecting, 20 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 45, Silent 20, Nonsense Mutation 6, Frame Shift Del 2, Splice Site 1, Translation Start Site 1, 3'Flank 1, Splice Region 1, RNA 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.272G>A p.W91* | Nonsense Mutation (SNP) | VAF 22/176 reads (13%) | hotspot (GDC flag); catalogued as COSV52734595, COSV53139118; called by muse, mutect2, varscan2
- AHDC1 | c.808G>A p.E270K | Missense Mutation (SNP) | VAF 12/81 reads (15%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.027); catalogued as rs1453259977, COSV55937289; called by muse, varscan2
- ALDH1B1 | c.262C>T p.R88C | Missense Mutation (SNP) | VAF 21/341 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs774671053, COSV66619506; called by muse, mutect2
- C9orf24 | c.135G>A p.P45= | Splice Region (SNP) | VAF 95/330 reads (29%) | catalogued as rs757617269; called by muse, mutect2, varscan2
- CACNG4 | c.827T>C p.M276T | Missense Mutation (SNP) | VAF 46/203 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.212); catalogued as rs762265124; called by muse, mutect2, varscan2
- CCNL2 | c.95C>T p.S32L | Missense Mutation (SNP) | VAF 36/76 reads (47%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as rs750408739; called by muse, varscan2
- CHRM2 | c.444G>T p.W148C | Missense Mutation (SNP) | VAF 13/89 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57778241; called by muse, mutect2, varscan2
- DSC2 | c.1420C>G p.P474A | Missense Mutation (SNP) | VAF 168/306 reads (55%) | SIFT tolerated (0.7); PolyPhen benign (0.005); catalogued as rs1354317356; called by muse, mutect2, varscan2
- EPN3 | c.667G>A p.E223K | Missense Mutation (SNP) | VAF 25/57 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99277596; called by muse, mutect2, varscan2
- IDE | c.172C>G p.P58A | Missense Mutation (SNP) | VAF 114/237 reads (48%) | SIFT tolerated (0.56); PolyPhen benign (0.009); catalogued as rs1445075843, COSV56423511; called by muse, mutect2, varscan2
- IL9R | c.59G>A p.R20Q | Missense Mutation (SNP) | VAF 150/310 reads (48%) | SIFT tolerated (0.55); PolyPhen benign (0.001); catalogued as rs372322566, COSV54899166; called by muse, mutect2, varscan2
- KMT2C | c.5929C>T p.Q1977* | Nonsense Mutation (SNP) | VAF 103/738 reads (14%) | catalogued as COSV51454142, COSV99030560; called by muse, mutect2, varscan2
- KMT2D | c.12649C>T p.Q4217* | Nonsense Mutation (SNP) | VAF 30/83 reads (36%) | catalogued as COSV56407982; called by muse, mutect2, varscan2
- LHFPL4 | c.643+2C>T p.X215_splice | Splice Site (SNP) | VAF 228/465 reads (49%) | catalogued as rs747204949; called by muse, mutect2, varscan2
- MLH3 | c.1469C>G p.S490C | Missense Mutation (SNP) | VAF 63/164 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.24); catalogued as COSV53153789, COSV99469879; called by muse, mutect2, varscan2
- MRTFA | c.1775C>T p.S592L | Missense Mutation (SNP) | VAF 19/86 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as rs199908950, COSV62932756; called by muse, mutect2, varscan2
- PCDHGA12 | c.689T>C p.V230A | Missense Mutation (SNP) | VAF 63/150 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.777); catalogued as rs775284049, COSV52752225; called by muse, mutect2, varscan2
- PCDHGA3 | c.1409C>T p.S470F | Missense Mutation (SNP) | VAF 162/305 reads (53%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.803); catalogued as rs756507522, COSV53902134, COSV54032096; called by muse, mutect2, varscan2
- PLEKHG5 | c.2654G>A p.R885Q (on ENST00000400915 / NM_001042663.3; = p.R848Q on NM_020631.6) | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT tolerated (0.96); PolyPhen benign (0); catalogued as rs761000380, COSV61069337; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RAPGEF3 | c.1223C>T p.S408F (on ENST00000389212; = p.S366F on NM_006105.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 48/109 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as rs1435656137; called by muse, mutect2, varscan2
- SHE | c.286G>A p.V96I | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as rs1335015387; called by muse, mutect2, varscan2
- SMPD2 | c.454del p.R152Vfs*40 | Frame Shift Del (DEL) | VAF 87/253 reads (34%) | catalogued as COSV57806697; called by mutect2, pindel, varscan2
- STAG2 | c.436C>T p.R146* | Nonsense Mutation (SNP) | VAF 78/83 reads (94%) | catalogued as COSV54364707; called by muse, mutect2, varscan2
- THRAP3 | c.68G>A p.R23H | Missense Mutation (SNP) | VAF 81/171 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs148045717; called by muse, mutect2, varscan2
- TRIML1 | c.1402G>A p.V468I | Missense Mutation (SNP) | VAF 49/111 reads (44%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0); catalogued as rs765434450, COSV60195900; called by muse, mutect2
- UNC5C | c.1768C>A p.P590T | Missense Mutation (SNP) | VAF 20/120 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as COSV71662581; called by muse, mutect2
- VLDLR | c.2395G>A p.A799T | Missense Mutation (SNP) | VAF 34/115 reads (30%) | SIFT tolerated (0.48); PolyPhen benign (0.306); catalogued as rs183359461; called by muse, varscan2
- VWCE | c.2831C>T p.P944L | Missense Mutation (SNP) | VAF 59/266 reads (22%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); catalogued as rs951052952; called by muse, mutect2, varscan2
- ZDHHC7 | c.745G>A p.E249K | Missense Mutation (SNP) | VAF 143/321 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.899); catalogued as rs758226485, COSV58212654; called by muse, mutect2, varscan2
- APLNR | c.142C>G p.L48V | Missense Mutation (SNP) | VAF 86/211 reads (41%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.487); called by muse, mutect2, varscan2
- ARRB1 | c.905C>G p.S302C | Missense Mutation (SNP) | VAF 201/435 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- ATP1A1 | c.526G>A p.E176K | Missense Mutation (SNP) | VAF 95/219 reads (43%) | SIFT tolerated (0.26); PolyPhen benign (0.233); called by muse, mutect2, varscan2
- BRD2 | c.2036C>G p.S679* | Nonsense Mutation (SNP) | VAF 48/126 reads (38%) | called by muse, mutect2, varscan2
- CFAP65 | c.2992G>A p.E998K | Missense Mutation (SNP) | VAF 141/234 reads (60%) | SIFT tolerated (0.14); PolyPhen benign (0.255); called by muse, mutect2, varscan2
- CLINT1 | c.450G>C p.K150N | Missense Mutation (SNP) | VAF 56/114 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- CORO1B | c.993del p.K331Nfs*20 | Frame Shift Del (DEL) | VAF 70/181 reads (39%) | called by mutect2, pindel, varscan2
- CPXM1 | c.1983G>T p.W661C | Missense Mutation (SNP) | VAF 22/123 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CTCFL | c.1139G>C p.R380T | Missense Mutation (SNP) | VAF 245/625 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.598); called by muse, mutect2, varscan2
- EPN3 | c.759G>C p.E253D | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated (0.05); PolyPhen benign (0.009); called by muse, mutect2
- EXOSC9 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 85/202 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- GABRB3 | c.1172C>G p.S391* | Nonsense Mutation (SNP) | VAF 105/243 reads (43%) | called by muse, mutect2, varscan2
- KRT13 | c.925A>T p.T309S | Missense Mutation (SNP) | VAF 250/563 reads (44%) | SIFT tolerated (0.92); PolyPhen benign (0.088); called by muse, mutect2, varscan2
- MACF1 | c.19289G>C p.R6430T (on ENST00000372915; = p.R4475T on NM_012090.5) | Missense Mutation (SNP) | VAF 36/72 reads (50%) | called by muse, mutect2, varscan2
- MS4A15 | c.467T>A p.I156N (on ENST00000405633 / NM_001098835.2; = p.I63N on NM_152717.3) | Missense Mutation (SNP) | VAF 38/64 reads (59%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); called by muse, mutect2, varscan2
- OR14J1 | c.17C>T p.S6L | Missense Mutation (SNP) | VAF 45/95 reads (47%) | SIFT tolerated (0.11); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- PICK1 | c.1074C>G p.F358L | Missense Mutation (SNP) | VAF 26/69 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); called by muse, varscan2
- PRKAG2 | c.608G>C p.R203T | Missense Mutation (SNP) | VAF 59/134 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.703); called by muse, mutect2, varscan2
- RIC8A | c.209T>A p.V70D | Missense Mutation (SNP) | VAF 45/184 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); called by muse, mutect2, varscan2
- SGMS1 | c.839A>G p.Y280C | Missense Mutation (SNP) | VAF 30/76 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- SLC38A10 | c.904G>A p.E302K | Missense Mutation (SNP) | VAF 90/458 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SPATA20 | c.1147G>A p.E383K (on ENST00000356488 / NM_001258372.1; = p.E399K on NM_022827.4) | Missense Mutation (SNP) | VAF 212/461 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, varscan2
- STARD10 | c.301G>C p.E101Q | Missense Mutation (SNP) | VAF 48/122 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.826); called by muse, mutect2, varscan2
- TEX2 | c.2800G>C p.E934Q (on ENST00000583097 / NM_001288733.2; = p.E941Q on NM_018469.5) | Missense Mutation (SNP) | VAF 639/907 reads (70%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.756); called by muse, mutect2, varscan2
- TYRP1 | c.1184C>A p.P395Q | Missense Mutation (SNP) | VAF 34/112 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- WDR59 | c.208C>T p.H70Y | Missense Mutation (SNP) | VAF 57/138 reads (41%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- XPR1 | c.1909G>C p.D637H | Missense Mutation (SNP) | VAF 51/120 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.839); called by muse, mutect2, varscan2
- BRD2 | c.1635C>G p.P545= | Silent (SNP) | VAF 55/119 reads (46%) | called by muse, mutect2, varscan2
- CCNL2 | c.231C>T p.L77= | Silent (SNP) | VAF 24/64 reads (38%) | catalogued as rs374243154, COSV100784949; called by muse, varscan2
- CELSR1 | c.2076C>T p.Y692= | Silent (SNP) | VAF 13/45 reads (29%) | catalogued as rs529594359, COSV53090406; called by muse, mutect2, varscan2
- DBF4B | c.1290C>T p.L430= | Silent (SNP) | VAF 66/157 reads (42%) | catalogued as COSV100154457; called by muse, mutect2, varscan2
- EFHB | c.2052C>G p.L684= | Silent (SNP) | VAF 66/161 reads (41%) | catalogued as COSV55546191; called by muse, mutect2, varscan2
- ETAA1 | c.1485A>G p.Q495= | Silent (SNP) | VAF 4/15 reads (27%) | catalogued as rs971704214; called by muse, mutect2, varscan2
- FGFR3 | c.927C>T p.L309= | Silent (SNP) | VAF 14/30 reads (47%) | catalogued as rs1405842619, COSV53416517, COSV53427150; called by muse, mutect2
- FKBP3 | c.85C>T p.L29= | Silent (SNP) | VAF 89/220 reads (40%) | called by muse, mutect2, varscan2
- FLT4 | c.2043G>A p.T681= | Silent (SNP) | VAF 63/117 reads (54%) | catalogued as rs1325289784, COSV56115106; called by muse, mutect2, varscan2
- INSM2 | c.1590C>T p.C530= | Silent (SNP) | VAF 23/135 reads (17%) | catalogued as rs774497773, COSV51897847; called by muse, mutect2, varscan2
- MISP | c.723C>T p.N241= | Silent (SNP) | VAF 35/62 reads (56%) | catalogued as rs754864934, COSV53119471; called by muse, mutect2, varscan2
- NEB | c.15648G>A p.L5216= | Silent (SNP) | VAF 13/114 reads (11%) | called by muse, mutect2, varscan2
- PARVB | c.1074C>T p.T358= | Silent (SNP) | VAF 9/145 reads (6%) | called by muse, mutect2
- PIK3R2 | c.1890G>A p.T630= | Silent (SNP) | VAF 34/69 reads (49%) | catalogued as rs965191886; called by muse, mutect2, varscan2
- PRAMEF1 | c.660G>C p.L220= | Silent (SNP) | VAF 494/980 reads (50%) | called by muse, mutect2, varscan2
- SPATA20 | c.1362G>A p.Q454= (on ENST00000356488 / NM_001258372.1; = p.Q470= on NM_022827.4) | Silent (SNP) | VAF 71/157 reads (45%) | called by muse, mutect2, varscan2
- ST7L | c.780A>G p.A260= | Silent (SNP) | VAF 85/176 reads (48%) | called by muse, mutect2, varscan2
- TDRD10 | c.249G>A p.V83= | Silent (SNP) | VAF 61/418 reads (15%) | called by muse, mutect2, varscan2
- ZBTB46 | c.1045C>T p.L349= | Silent (SNP) | VAF 139/297 reads (47%) | called by muse, mutect2, varscan2
- ZFP36L1 | c.918G>C p.L306= | Silent (SNP) | VAF 108/255 reads (42%) | catalogued as rs1392960726, COSV60547607; called by muse, mutect2, varscan2
- FAM153CP | chr5:178055981 G>A | 3'Flank (SNP) | VAF 69/152 reads (45%) | called by muse, mutect2, varscan2
- PRR12 | c.52-258G>A | Intron (SNP) | VAF 12/32 reads (38%) | catalogued as rs774901947, COSV69820179; called by muse, mutect2, varscan2
- SNORD116-1 | n.89G>C | RNA (SNP) | VAF 92/228 reads (40%) | called by muse, mutect2, varscan2
